Gene-level copy-number profile of tumor specimen ALCH-ACFN-TTP1-A from ALCHEMIST case ALCH-ACFN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.0 years (24,097 days).
Specimen ALCH-ACFN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 03569834-3b28-4e43-8d66-939f352eefbe.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ACFN-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,262 have no estimate.
https://portal.gdc.cancer.gov/files/2830c547-2dca-4ae5-a8d1-de099442ab15

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 189; copy number 1: 12,098; copy number 2: 37,909; copy number 3: 6,791; copy number 4: 1,098; copy number 5: 114; copy number 6: 38; copy number 7: 121; copy number 9: 1; copy number 10: 1; copy number 36: 1.

Homozygous deletions (total copy number 0; autosomes only): 186 genes in 78 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:62,208,136–62,211,666, 2 genes (within-gene range 0–3): AL162739.1, Y_RNA.
- chr1:109,046,828–109,076,003, 2 genes: RANP5, TAF13.
- chr2:24,971,390–25,039,716, 3 genes (within-gene range 0–2): DNAJC27-AS1, AC013267.1, Y_RNA.
- chr2:25,926,598–25,995,081, 2 genes: KIF3C, UQCRHP2.
- chr2:44,154,789–44,168,859, 3 genes (within-gene range 0–2): RNU6-566P, PDSS1P2, AC019129.2.
- chr2:86,861,825–86,912,978, 2 genes (within-gene range 0–4): ANAPC1P1, AC111200.1.
- chr2:89,872,463–89,916,052, 6 genes: IGKV2D-38, IGKV1D-37, IGKV2D-36, IGKV1D-35, IGKV3D-34, IGKV1D-33.
- chr2:90,179,889–91,621,421, 12 genes (within-gene range 0–2): IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1.
- chr2:91,674,857–91,723,605, 4 genes: RNA5SP100, DRD5P1, AC027612.2, NKAIN1P2.
- chr2:91,775,944–91,880,195, 5 genes: GGT8P, IGKV1OR2-1, ABCD1P5, AC127391.1, PABPC1P6.
- chr3:109,293,788–109,364,234, 4 genes: DPPA2, Metazoa_SRP, DPPA4, AC124945.1.
- chr7:72,947,581–73,005,922, 5 genes (within-gene range 0–2): NSUN5P2, TRIM74, STAG3L3, AC211476.1, Y_RNA.
- chr7:73,732,569–73,738,867, 3 genes: RN7SL265P, ABHD11-AS1, ABHD11.
- chr7:128,830,406–128,862,626, 2 genes (within-gene range 0–2): FLNC, FLNC-AS1.
- chr8:12,128,107–12,139,077, 3 genes (within-gene range 0–1): AC130366.1, USP17L7, USP17L2.
- chr8:23,702,451–23,789,487, 3 genes (within-gene range 0–1): NKX2-6, AC012574.1, AC012574.2.
- chr8:30,774,457–30,913,008, 2 genes: PPP2CB, TEX15.
- chr8:37,934,281–37,965,953, 2 genes (within-gene range 0–4): GOT1L1, AC144573.1.
- chr8:38,030,534–38,063,791, 2 genes: EIF4EBP1, AP006545.1.
- chr9:61,581,813–61,662,690, 4 genes: AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr9:136,812,788–136,831,023, 2 genes (within-gene range 0–1): NCLP1, MIR4292.
- chr14:18,343,038–18,419,273, 3 genes: RNU6-458P, CR383658.2, BNIP3P6.
- chr15:28,881,667–29,118,315, 3 genes (within-gene range 0–1): AC174469.1, APBA2, AC127522.1.
- chr15:50,354,959–50,689,193, 12 genes (within-gene range 0–2): GABPB1-AS1, AC022087.1, MIR4712, AHCYP7, USP8, RNA5SP395, AC012170.1, USP50, TRPM7, AC084756.1, AC084756.2, RN7SL354P.
- chr16:46,469,341–46,790,407, 13 genes (within-gene range 0–2): ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3.
- chr17:1,420,689–1,463,162, 2 genes: CRK, AC032044.1.
- chr17:1,829,702–1,900,082, 2 genes (within-gene range 0–1): RPA1, AC130689.1.
- chr17:2,557,753–2,587,866, 2 genes: RN7SL33P, EIF4A1P9.
- chr17:4,787,057–4,790,589, 2 genes: AC233723.2, GLTPD2.
- chr17:12,982,613–13,018,065, 3 genes (within-gene range 0–1): AC005277.2, AC005277.1, ELAC2.
- chr18:21,240,675–21,525,417, 3 genes (within-gene range 0–1): AC022809.1, GREB1L, AC015878.2.
- chr19:6,306,142–6,362,149, 2 genes (within-gene range 0–1): ACER1, AC011491.3.
- chr19:6,375,148–6,424,794, 8 genes (within-gene range 0–1): PSPN, GTF2F1, AC011491.2, MIR6885, MIR6790, AC011491.1, KHSRP, MIR3940.
- chr19:11,451,326–11,505,839, 4 genes: ELAVL3, AC008481.3, ZNF653, MIR7974.
- chr19:11,559,374–11,619,161, 3 genes: ZNF627, ACP5, GAPDHP76.
- chr19:14,514,769–14,565,980, 2 genes (within-gene range 0–1): DNAJB1, TECR.
- chr19:16,630,743–16,660,442, 4 genes (within-gene range 0–1): AC024075.3, SMIM7, AC024075.2, AC024075.1.
- chr19:23,596,122–23,603,106, 3 genes (within-gene range 0–1): AC073544.1, RPS27P29, VN1R93P.
- chr20:346,782–397,559, 2 genes (within-gene range 0–2): NRSN2, TRIB3.
- chr20:63,861,212–63,864,293, 2 genes: AL118506.1, ABHD16B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 276 genes in 50 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:47,760,528–47,997,385, 1 gene, copy number 6 (within-gene range 4–6): TRABD2B.
- chr1:47,818,066–48,472,208, 12 genes, copy number 5 (within-gene range 4–6): AC096541.1, LINC02794, AL356289.1, CYP46A4P, SKINT1L, AL356289.2, AL109659.1, SLC5A9, AL109659.2, AL109659.3, SPATA6, PPP1R8P1.
- chr1:48,435,967–48,497,736, 3 genes, copy number 5: AL356968.2, RNU4-61P, AL356968.1.
- chr1:234,629,311–234,736,720, 6 genes, copy number 5: LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, LINC01132.
- chr4:1,113,639–1,153,726, 4 genes, copy number 5: AC092535.4, TMED11P, AC092535.1, AC092535.2.
- chr5:58,198–189,972, 2 genes, copy number 5 (within-gene range 3–5): AC113430.1, PLEKHG4B.
- chr5:191,495–196,334, 1 gene, copy number 5 (within-gene range 4–5): LRRC14B.
- chr5:269,858–271,516, 1 gene, copy number 10: AC021087.1.
- chr5:602,620–612,210, 1 gene, copy number 5: AC106772.1.
- chr5:795,606–919,357, 5 genes, copy number 6: ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3.
- chr5:150,690,792–150,701,077, 1 gene, copy number 6: RBM22.
- chr6:32,934,629–32,969,094, 3 genes, copy number 5 (within-gene range 3–5): HLA-DMB, AL645941.2, HLA-DMA.
- chr7:7,156,934–7,278,071, 3 genes, copy number 5: C1GALT1, AC005532.2, AC005532.1.
- chr7:42,901,272–42,948,958, 6 genes, copy number 5: AC010132.4, C7orf25, AC010132.3, PSMA2, AC010132.2, MRPL32.
- chr7:73,220,624–73,301,161, 3 genes, copy number 6–7: NCF1B, GTF2IRD2P1, POM121B.
- chr8:12,095,176–12,115,516, 2 genes, copy number 7–36: DEFB108D, ZNF705D.
- chr8:66,112,667–66,197,315, 4 genes, copy number 5: AC084082.1, TRIM55, CRH, LINC00967.
- chr8:80,967,810–81,284,777, 8 genes, copy number 5–6: PAG1, AC022778.1, AC079209.2, AC079209.1, AC009902.1, AC009902.3, AC009902.2, FABP5.
- chr8:93,939,364–93,974,776, 3 genes, copy number 5: PSMA2P2, RPL34P18, AC105081.1.
- chr8:95,066,808–95,087,924, 4 genes, copy number 5 (within-gene range 4–5): MIR3150BHG, AC068189.1, MIR3150B, MIR3150A.
- chr8:100,380,486–100,464,613, 3 genes, copy number 6 (within-gene range 4–6): AP003472.1, MIR4471, AP003472.2.
- chr8:103,298,433–103,332,866, 2 genes, copy number 5 (within-gene range 4–5): FZD6, AC025370.2.
- chr8:123,680,794–123,815,452, 2 genes, copy number 5: ANXA13, FAM91A1.
- chr8:124,450,820–124,488,618, 3 genes, copy number 5 (within-gene range 4–5): TRMT12, RNF139-AS1, RNF139.
- chr8:124,973,295–125,367,120, 7 genes, copy number 5 (within-gene range 3–5): ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P.
- chr8:125,859,721–126,292,788, 3 genes, copy number 5 (within-gene range 4–5): LINC00861, RNU6-442P, SOD1P3.
- chr8:127,072,694–127,227,541, 3 genes, copy number 5 (within-gene range 4–5): CASC19, PRNCR1, AC020688.1.
- chr8:132,507,962–133,409,107, 17 genes, copy number 5–7: HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6.
- chr8:133,754,811–133,814,537, 5 genes, copy number 5: MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3.
- chr8:133,946,677–133,963,259, 2 genes, copy number 5: AC110741.3, AC110741.2.
- chr8:135,455,865–135,656,722, 3 genes, copy number 5: AC040914.1, KHDRBS3, MAPRE1P1.
- chr8:139,096,305–139,508,971, 5 genes, copy number 5–6: AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1.
- chr8:142,657,460–142,778,224, 12 genes, copy number 5–7: JRK, PSCA, LY6K, LNCOC1, THEM6, AC108002.1, SLURP1, LYPD2, AC083841.1, LYNX1-SLURP2, SLURP2, LYNX1.
- chr8:142,785,374–142,812,120, 2 genes, copy number 7 (within-gene range 4–7): AC083841.2, AC083841.4.
- chr8:142,834,247–142,916,506, 3 genes, copy number 5 (within-gene range 2–5): GML, ZNHIT1P1, CYP11B1.
- chr11:35,132,655–35,232,402, 2 genes, copy number 5 (within-gene range 2–5): AL356215.1, CD44.
- chr12:67,065,018–73,208,317, 112 genes, copy number 6–7 (within-gene range 2–7) (broad region; genes not listed).
- chr14:105,583,731–105,588,395, 1 gene, copy number 9: IGHA2.
- chr17:18,476,737–18,494,945, 1 gene, copy number 7: LGALS9C.
- chr19:46,101,122–46,196,218, 5 genes, copy number 5 (within-gene range 3–5): AC007785.1, AC007785.2, IGFL3, TGIF1P1, IGFL2.

Autosomal genes at a single copy (total copy number 1): 12,094. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
